Somatic mutation profile of tumor specimen TCGA-32-2634-01A (aliquot TCGA-32-2634-01A-01D-1495-08) from TCGA case TCGA-32-2634, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.0 years (29,964 days).
Specimen TCGA-32-2634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1305e87-ff06-4f68-a7d4-6a20669e914a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2634-10A (Blood Derived Normal), aliquot TCGA-32-2634-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3d93020-5118-4a15-9f91-c6923819ecfb

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs57374291, CM1111458, CM131884, COSV64291957, COSV64294035, COSV64296475; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 52/64 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330865474, CM151471, COSV52674699, COSV52714188, COSV52767322; ClinVar: uncertain significance; called by muse, varscan2
- ABCA13 | c.7235C>G p.A2412G | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs373658653; called by muse, mutect2, varscan2
- AL136295.1 | c.1608G>A p.M536I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs759347812, COSV55780555; called by muse, mutect2, varscan2
- ANO2 | c.2770A>T p.I924F (on ENST00000356134 / NM_001278597.3; = p.I928F on NM_001278596.3) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59029388; called by muse, mutect2, varscan2
- BANK1 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59845157; called by muse, mutect2
- CACNA1A | c.4962G>A p.G1654= | Splice Region (SNP) | VAF 20/62 reads (32%) | catalogued as COSV64201662; called by muse, mutect2, varscan2
- CACNA2D1 | c.2956G>A p.D986N (on ENST00000356253 / NM_001366867.1; = p.D974N on NM_000722.4) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs774285483, COSV62382873; called by muse, mutect2, varscan2
- CHRDL2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756931331, COSV55221656; called by muse, mutect2, varscan2
- DHRS11 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 146/166 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs148449399; called by muse, mutect2, varscan2
- DNAH5 | c.5605A>G p.T1869A | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54234314; called by muse, mutect2, varscan2
- DSC3 | c.672T>A p.D224E | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV64573667; called by muse, mutect2, varscan2
- EPS8L1 | c.1019C>T p.P340L (on ENST00000201647 / NM_133180.3; = p.P213L on NM_017729.3) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52383444; called by muse, mutect2, varscan2
- IL6 | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV51733177; called by muse, mutect2, varscan2
- KDM1A | c.759_760del p.H253Qfs*15 | Frame Shift Del (DEL) | VAF 134/272 reads (49%) | catalogued as rs753380832; called by pindel, varscan2
- KIT | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV55407132; called by muse, mutect2, varscan2
- LAMA3 | c.8525C>T p.T2842M (on ENST00000313654 / NM_198129.4; = p.T1233M on NM_000227.6) | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs774819338, COSV52537183; called by muse, mutect2, varscan2
- MAN2B2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as rs372535950, COSV53457402; called by muse, mutect2, varscan2
- MUC5AC | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); catalogued as COSV62254405; called by mutect2, varscan2
- NOD1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1332709505, COSV56113234; called by muse, mutect2, varscan2
- OTUD4 | c.2167C>T p.P723S (on ENST00000447906 / NM_001366057.1; = p.P658S on NM_001102653.1) | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71381907, COSV71381999; called by muse, mutect2, varscan2
- PACRG | c.287G>A p.W96* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | catalogued as COSV61308144; called by muse, mutect2, varscan2
- PIK3R1 | c.1714C>T p.Q572* (on ENST00000521381 / NM_181523.3; = p.Q302* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | catalogued as rs1390357148, COSV57132417; called by muse, mutect2, varscan2
- PRDM9 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as COSV57004806, COSV57006871, COSV57008322; called by muse, mutect2, varscan2
- RB1 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 46/55 reads (84%) | catalogued as CM030516, COSV57295380; called by muse, mutect2, varscan2
- RNF111 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs774394311, COSV62086436, COSV62087506; called by muse, mutect2, varscan2
- RNF130 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV56151378; called by muse, mutect2, varscan2
- RPE | c.385G>A p.A129T (on ENST00000359429 / NM_001318926.1; = p.A79T on NM_006916.2) | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV55993612; called by muse, mutect2, varscan2
- SEMA3C | c.923T>A p.V308E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54849169; called by muse, mutect2, varscan2
- SIK2 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752159549, COSV59253595; called by muse, mutect2, varscan2
- SIMC1 | c.1192C>T p.P398S (on ENST00000443967 / NM_001308196.1; = p.P417S on NM_001308195.2) | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.03); catalogued as COSV57904399; called by muse, mutect2, varscan2
- SLC6A14 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 92/108 reads (85%) | catalogued as COSV64146030, COSV64147554; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- TRIM11 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52858512; called by muse, mutect2, varscan2
- ZFP28 | c.1941T>G p.C647W | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56736518; called by muse, mutect2, varscan2
- EXPH5 | c.3002del p.S1001Tfs*40 | Frame Shift Del (DEL) | VAF 83/228 reads (36%) | called by mutect2, pindel, varscan2
- NISCH | c.1923_1934del p.E644_E647del | In Frame Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel
- NTAQ1 | c.93del p.N31Kfs*17 | Frame Shift Del (DEL) | VAF 100/270 reads (37%) | called by mutect2, pindel, varscan2
- ATP4A | c.636C>T p.A212= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs149880813; called by muse, mutect2, varscan2
- FTMT | c.183C>T p.P61= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1206980369, COSV58420621; called by muse, varscan2
- HCFC2 | c.405T>C p.Y135= | Silent (SNP) | VAF 169/392 reads (43%) | catalogued as COSV57558990; called by muse, mutect2, varscan2
- HRNR | c.7434T>A p.S2478= | Silent (SNP) | VAF 18/142 reads (13%) | called by mutect2, varscan2
- MAP1A | c.4113C>T p.D1371= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV55810150; called by muse, mutect2, varscan2
- NABP1 | c.276G>A p.R92= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV57138964; called by muse, mutect2, varscan2
- NFKB2 | c.1017G>T p.R339= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV50048005; called by muse, mutect2, varscan2
- NSFL1C | c.1063C>T p.L355= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV53794010, COSV99401269; called by muse, mutect2
- OR4D6 | c.723G>A p.T241= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as rs758572267, COSV100271754, COSV55660072; called by muse, mutect2, varscan2
- OR51L1 | c.543T>C p.C181= | Silent (SNP) | VAF 75/212 reads (35%) | catalogued as COSV58625083; called by muse, mutect2, varscan2
- RABGEF1 | c.363T>C p.S121= (on ENST00000439720 / NM_001287061.2; = p.S108= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV53163088; called by muse, mutect2, varscan2
- SERPINA4 | c.867T>A p.I289= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV54070207, COSV54070516; called by muse, mutect2, varscan2
